Somatic mutation profile of tumor specimen 0DQFJ6 from CCDI case PBCEXH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 12.4 years (4,525 days).
Specimen 0DQFJ6: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54e5c3ff-5857-46cd-b648-0a13f1199569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQFIY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aebb79c1-4028-489a-a436-f19046817531

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 4, Intron 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRG3 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 106/346 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs768588213, COSV61518560; called by muse, mutect2, varscan2
- HECTD4 | c.3507T>A p.D1169E | Missense Mutation (SNP) | VAF 195/410 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1242960106; called by muse, mutect2, varscan2
- NID2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 25/337 reads (7%) | catalogued as COSV53494494; called by muse, mutect2
- P2RY6 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369328048, COSV62935600; called by muse, varscan2
- PIANP | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 128/310 reads (41%) | catalogued as rs1280893962; called by muse, mutect2, varscan2
- THUMPD3 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 56/472 reads (12%) | catalogued as rs367884819; called by muse, mutect2, varscan2
- TUBGCP6 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745791632; called by muse, mutect2, varscan2
- VPS13B | c.10726G>A p.A3576T | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs528991858, COSV62157793; called by muse, varscan2
- ABCC1 | c.1334G>T p.W445L | Missense Mutation (SNP) | VAF 148/493 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKS1B | c.2588G>C p.R863T (on ENST00000547776 / NM_152788.4; = p.R89T on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/399 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRNA4 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNA4 | c.638A>G p.D213G | Missense Mutation (SNP) | VAF 68/430 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2
- DNAH12 | c.4687G>T p.E1563* (on ENST00000351747; = p.E1586* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 89/347 reads (26%) | called by muse, mutect2, varscan2
- LTBP1 | c.1527G>T p.Q509H (on ENST00000404816 / NM_206943.4; = p.Q183H on NM_000627.4) | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MCTP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MORN3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 46/642 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- MUC12 | c.15176G>A p.G5059E (on ENST00000379442; = p.G4916E on NM_001164462.1) | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT tolerated (0.34); called by muse, varscan2
- PAICS | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 50/333 reads (15%) | PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TMPRSS15 | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF517 | c.243A>T p.E81D | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CHRNA4 | c.447G>C p.V149= | Silent (SNP) | VAF 60/378 reads (16%) | called by muse, varscan2
- HRH1 | c.939G>A p.A313= | Silent (SNP) | VAF 76/293 reads (26%) | catalogued as rs369793859, COSV67955871; called by muse, mutect2, varscan2
- MGAM2 | c.2946C>T p.A982= | Silent (SNP) | VAF 38/324 reads (12%) | catalogued as rs1049402579; called by muse, varscan2
- EPS8L3 | c.1564-34A>G | Intron (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- KIF2A | c.1027+81T>C | Intron (SNP) | VAF 47/171 reads (27%) | called by muse, mutect2, varscan2
- RNF207 | c.942+76G>C | Intron (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
